Somatic mutation profile of tumor specimen 0DCUL4 from CCDI case PBBMYG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.9 years (1,414 days).
Specimen 0DCUL4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff31a6a0-5e4b-46fe-b9e9-7d8d8e574457.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCUKU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89df6ee8-7dd8-44e8-a3e0-e76ef5de6d18

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCB1 | c.463C>T p.R155* (on ENST00000263121; = p.R201* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 157/222 reads (71%) | catalogued as rs1555877286, CM992975, COSV54093216; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DBX1 | c.209C>G p.A70G | Missense Mutation (SNP) | VAF 126/716 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.057); catalogued as COSV99910210; called by mutect2, varscan2
- EDRF1 | c.1413G>T p.K471N (on ENST00000356792 / NM_001202438.2; = p.K437N on NM_015608.2) | Missense Mutation (SNP) | VAF 231/485 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as COSV100523725; called by muse, mutect2, varscan2
- RGS13 | c.156A>T p.L52F | Missense Mutation (SNP) | VAF 211/484 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334296203; called by muse, mutect2, varscan2
- MYH6 | c.2229dup p.T744Dfs*11 | Frame Shift Ins (INS) | VAF 397/991 reads (40%) | called by mutect2, pindel, varscan2
- STRIP2 | c.677C>G p.T226R | Missense Mutation (SNP) | VAF 236/636 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- EEF1AKMT3 | c.417C>G p.V139= | Silent (SNP) | VAF 19/573 reads (3%) | called by muse, mutect2
- PEX26 | c.270C>T p.I90= | Silent (SNP) | VAF 39/1429 reads (3%) | catalogued as COSV61605187; called by muse, mutect2
- HDHD5 | c.538-27G>A | Intron (SNP) | VAF 22/754 reads (3%) | called by muse, mutect2
- PRKCSH | c.1175+66T>A | Intron (SNP) | VAF 16/323 reads (5%) | called by muse, mutect2
